Gene-level copy-number profile of tumor specimen TCGA-E7-A541-01A from TCGA case TCGA-E7-A541, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 66.3 years (24,206 days).
Specimen TCGA-E7-A541-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.97072505-248b-4416-95e6-cbda9131c6ab.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-E7-A541-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d354783d-8f40-430c-9b28-cfcb1aa054bd

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 62; copy number 1: 6; copy number 2: 1,001; copy number 3: 9,023; copy number 4: 19,169; copy number 5: 9,256; copy number 6: 15,675; copy number 7: 3,067; copy number 8: 531; copy number 9: 418; copy number 10: 323; copy number 11: 111; copy number 12: 900; copy number 13: 133; copy number 15: 21; copy number 16: 2; copy number 17: 91; copy number 20: 5; copy number 31: 10; copy number 53: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-E7-A541-01A-11D-A26L-01): tumor purity 0.39, ploidy 5.25, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 62 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:48,303,744–48,599,436, 1 gene (within-gene range 0–2): RB1.
- chr13:48,389,567–51,200,252, 61 genes (within-gene range 0–3) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,029 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:151,612,006–152,911,886, 73 genes, copy number 9 (broad region; genes not listed).
- chr1:160,485,030–163,509,595, 112 genes, copy number 12–17 (broad region; genes not listed).
- chr2:59,014,354–61,051,990, 33 genes, copy number 9 (within-gene range 6–9): AC007092.1, LINC01793, AC007100.1, AC007179.2, AC007179.1, AC007179.3, RNU6-508P, RNA5SP94, AC007100.2, AC007132.1, MIR4432HG, AC007381.1, RNU1-32P, MIR4432, BCL11A, AC009970.1, RN7SL361P, IFITM3P9, RPL26P13, RNU6-612P, ATP1B3P1, PAPOLG, LINC01185, RN7SL632P, RPL21P33, REL, RNU4-51P, AC010733.1, NONOP2, RPS12P3, PUS10, RNA5SP95, PEX13.
- chr4:73,986,439–77,702,803, 83 genes, copy number 10–13 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 12 (broad region; genes not listed).
- chr6:18,223,860–21,602,383, 42 genes, copy number 9: DEK, Y_RNA, AL138825.1, RNU6-263P, DDX18P3, IMPDH1P9, RNF144B, MIR548A1HG, MIR548A1, AL589647.1, AL357052.1, LNC-LBCS, RPL5P20, RNA5SP205, KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL022726.1, AL008627.1, MBOAT1, AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3.
- chr6:21,822,536–21,822,737, 1 gene, copy number 9: AL136313.1.
- chr6:123,216,339–123,685,323, 4 genes, copy number 9 (within-gene range 9–31): TRDN, TRDN-AS1, AL445259.1, AL133257.1.
- chr6:123,823,240–123,829,285, 1 gene, copy number 31: AL354936.1.
- chr6:129,576,132–130,574,112, 11 genes, copy number 9: ARHGAP18, RPL5P21, AL451046.2, B3GALNT2P1, AL451046.1, TMEM244, L3MBTL3, AL355581.1, SAMD3, TMEM200A, Y_RNA.
- chr6:133,502,252–133,892,802, 1 gene, copy number 10 (within-gene range 7–10): TARID.
- chr6:133,676,729–135,497,765, 38 genes, copy number 10–31 (within-gene range 7–31): FTH1P26, LINC01312, TCF21, TBPL1, AL035699.1, SLC2A12, AL449363.1, AL449363.2, HMGA1P7, RN7SL408P, SGK1, RPS29P32, RNA5SP218, Y_RNA, AL355881.1, KRT8P42, LINC01010, Z84486.1, CHCHD2P4, CT69, AL078590.2, FAM8A6P, AL078590.1, AL596188.1, AL121970.1, MEMO1P2, ALDH8A1, AL445190.1, HBS1L, MIR3662, AL353596.1, MYB, MYB-AS1, MIR548A2, AL023693.1, AHI1, AL049552.1, AL049552.2.
- chr8:88,326,836–93,850,075, 72 genes, copy number 12–20 (within-gene range 6–20) (broad region; genes not listed).
- chr8:99,960,936–102,124,907, 59 genes, copy number 10 (within-gene range 5–10): RGS22, SNORD77B, AC021590.1, FBXO43, POLR2K, SPAG1, Y_RNA, AC025647.1, Y_RNA, RNF19A, AP001574.1, AP003472.1, MIR4471, AP003472.2, AP000424.1, AP000424.2, ANKRD46, GAPDHP62, SNX31, AP001205.1, RNU6-1092P, PABPC1, MIR7705, RNU6ATAC41P, Y_RNA, RPS20P23, RNU4-83P, RPS26P6, Metazoa_SRP, AC027373.1, YWHAZ, RN7SL685P, FLJ42969, AP003469.2, AP003469.1, RN7SKP249, AP003469.3, ZNNT1, ZNF706, AP001330.4, AP001330.2, LINC02844, AP001330.5, AP001330.1, RNU7-67P, AP001330.3, NACA4P, DUXAP2, LINC02845, RN7SL563P, AP001208.1, AP001207.3, GRHL2, AP001207.2, AP001207.1, NCALD, AP000426.1, AP001329.1, PDCL3P2.
- chr8:104,981,164–105,288,365, 6 genes, copy number 11: AC090142.2, AC090142.3, AC090142.1, AC021546.1, TMCC1P1, AC041039.1.
- chr8:123,851,987–124,580,648, 19 genes, copy number 15 (within-gene range 8–15): FER1L6, AC090753.1, FER1L6-AS1, AC100871.2, FER1L6-AS2, AC100871.1, ARF1P3, AC090921.1, RNU6-756P, AC090192.2, AC090192.1, TMEM65, TRMT12, RNF139-AS1, RNF139, TATDN1, AC090198.1, MIR6844, NDUFB9.
- chr8:132,061,486–132,481,095, 2 genes, copy number 15 (within-gene range 6–15): HHLA1, KCNQ3.
- chr8:135,859,369–137,092,183, 1 gene, copy number 16 (within-gene range 6–16): LINC02055.
- chr8:137,105,352–137,105,458, 1 gene, copy number 16: RNU6-144P.
- chr8:137,696,724–138,914,041, 6 genes, copy number 11: AC110053.1, AC046195.1, AC046195.2, AC079015.1, FAM135B, COL22A1.
- chr9:79,135,374–80,782,770, 15 genes, copy number 53: AL512634.1, CHCHD2P9, LNCARSR, TLE4, AL161912.3, NPAP1P6, AL161912.1, AL161912.2, AL161912.4, AL161782.1, LINC01507, NPAP1P4, MTCO1P51, MTND2P9, RPS19P6.
- chr10:77,776,951–78,029,515, 10 genes, copy number 11 (within-gene range 3–11): RNU6-1266P, IMPDH1P5, AL450306.1, DLG5, AL391421.1, RN7SL284P, DLG5-AS1, H2AZP5, Metazoa_SRP, POLR3A.
- chr12:59,812,102–76,722,286, 297 genes, copy number 9–13 (broad region; genes not listed).
- chr12:93,569,814–95,791,189, 49 genes, copy number 10: SOCS2, AC012085.1, CRADD, AC012085.2, RN7SL630P, AC012464.2, AC012464.1, AC012464.3, RN7SKP263, AC123567.1, PLXNC1, AC123567.2, AC073655.3, AC073655.1, AC073655.2, CEP83, RN7SL330P, RBMS2P1, CEP83-DT, AC023161.1, RN7SL483P, NSA2P2, SUCLG2P2, MIR5700, TMCC3, MIR7844, LSM3P2, KRT19P2, MIR492, NDUFA12, NR2C1, FGD6, AC126615.2, AC126615.1, VEZT, Y_RNA, CBX3P5, RNU6-808P, MIR331, MIR3685, AC084879.1, AC084879.2, RNU6-735P, AC018475.1, METAP2, USP44, PGAM1P5, Y_RNA, NTN4.
- chr12:95,792,529–95,823,307, 2 genes, copy number 10 (within-gene range 7–10): RNU6-247P, LINC02410.
- chr20:31,257,664–33,792,269, 102 genes, copy number 12 (within-gene range 6–12) (broad region; genes not listed).
- chr22:24,006,305–26,618,027, 86 genes, copy number 9 (broad region; genes not listed).
- chr22:29,758,758–31,618,588, 89 genes, copy number 11 (within-gene range 5–11) (broad region; genes not listed).
- chr22:35,738,736–38,214,778, 104 genes, copy number 10 (within-gene range 6–10) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
